Somatic mutation profile of tumor specimen 0DUXP0 from CCDI case PBCMAS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 16.8 years (6,145 days).
Specimen 0DUXP0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff03615d-7dae-42c9-8109-8d1a92f67ea0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUXNZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6a04bfa-bd79-439d-83f2-8fd1667fd831

The open-access MAF lists 34 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 6, 3'UTR 3, Intron 3, 5'UTR 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1966A>G p.K656E (on ENST00000447712 / NM_023110.3; = p.K654E on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 303/644 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs869320694, COSV58327161, COSV58340654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 237/544 reads (44%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CHEK2 | c.869C>G p.A290G (on ENST00000382580 / NM_001005735.2; = p.A247G on NM_007194.4) | Missense Mutation (SNP) | VAF 304/812 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60423597; called by muse, mutect2, varscan2
- FGFR1 | c.1681G>A p.V561M (on ENST00000447712 / NM_023110.3; = p.V559M on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 197/407 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58333193; called by muse, mutect2, varscan2
- PTCRA | c.44C>A p.P15Q | Missense Mutation (SNP) | VAF 106/404 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.476); catalogued as COSV100485823; called by muse, mutect2, varscan2
- VPS18 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 78/157 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs202034474, COSV55028959; called by muse, mutect2, varscan2
- AL121899.2 | c.1375T>A p.Y459N | Missense Mutation (SNP) | VAF 22/376 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATRX | c.1079_1082del p.I360Rfs*6 | Frame Shift Del (DEL) | VAF 395/432 reads (91%) | called by mutect2, pindel, varscan2
- BICRAL | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 120/456 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- CCDC138 | c.561A>G p.I187M | Missense Mutation (SNP) | VAF 21/690 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- CCDC59 | c.55G>C p.G19R | Missense Mutation (SNP) | VAF 617/995 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- DOCK8 | c.1197G>T p.M399I | Missense Mutation (SNP) | VAF 292/742 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- OSBPL11 | c.2123A>T p.E708V | Missense Mutation (SNP) | VAF 48/979 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTK6 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 251/404 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- PTPN22 | c.70T>A p.F24I | Missense Mutation (SNP) | VAF 193/494 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- SGCB | c.386G>C p.G129A | Missense Mutation (SNP) | VAF 336/802 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLIT2 | c.313C>A p.L105I | Missense Mutation (SNP) | VAF 366/933 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- UMOD | c.1481G>T p.G494V | Missense Mutation (SNP) | VAF 184/441 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 66/1793 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- ZNF596 | c.959C>G p.S320C | Missense Mutation (SNP) | VAF 352/819 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CUEDC1 | c.756C>T p.N252= | Silent (SNP) | VAF 227/741 reads (31%) | called by muse, mutect2, varscan2
- DAB2 | c.1380T>G p.A460= | Silent (SNP) | VAF 257/584 reads (44%) | catalogued as rs984076003; called by muse, mutect2, varscan2
- MTMR11 | c.210G>C p.L70= | Silent (SNP) | VAF 239/913 reads (26%) | called by muse, mutect2, varscan2
- NBPF12 | c.801C>T p.A267= | Silent (SNP) | VAF 44/222 reads (20%) | called by muse, mutect2, varscan2
- NLRP8 | c.3102C>T p.P1034= | Silent (SNP) | VAF 264/502 reads (53%) | catalogued as rs142444217; called by muse, mutect2, varscan2
- ROMO1 | c.39A>C p.P13= | Silent (SNP) | VAF 238/536 reads (44%) | called by muse, mutect2, varscan2
- CCT4 | c.-45T>C | 5'UTR (SNP) | VAF 51/96 reads (53%) | called by muse, mutect2, varscan2
- DNTT | c.-45G>A | 5'UTR (SNP) | VAF 12/330 reads (4%) | called by muse, mutect2
- DYNLL1 | c.132+9G>A | Intron (SNP) | VAF 110/268 reads (41%) | catalogued as rs770835573; called by muse, mutect2, varscan2
- EEF1AKMT2 | c.292-25A>T | Intron (SNP) | VAF 12/256 reads (5%) | called by muse, mutect2
- KDM5B | c.3424-63C>G | Intron (SNP) | VAF 78/253 reads (31%) | called by muse, mutect2, varscan2
- PPP1R15B | c.*87A>T | 3'UTR (SNP) | VAF 25/146 reads (17%) | called by muse, mutect2, varscan2
- SUSD3 | c.*99G>T | 3'UTR (SNP) | VAF 21/63 reads (33%) | called by muse, mutect2, varscan2
- TRMT13 | c.*17G>A | 3'UTR (SNP) | VAF 298/647 reads (46%) | called by muse, mutect2, varscan2
